Somatic mutation profile of tumor specimen TCGA-CD-5801-01A (aliquot TCGA-CD-5801-01A-11D-1600-08) from TCGA case TCGA-CD-5801, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen TCGA-CD-5801-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c232da2f-5980-44d2-838f-43faca7695ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5801-10A (Blood Derived Normal), aliquot TCGA-CD-5801-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f799f9a-2b68-48c1-8207-610a49dfe0aa

The open-access MAF lists 428 somatic variants for this specimen: 331 protein-altering or splice-affecting, 88 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 88, Nonsense Mutation 8, Splice Region 6, Intron 5, Splice Site 3, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, Nonstop Mutation 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K2 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121434498, CM080435, CM086853, COSV53562382, COSV53564387; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV99288864; called by muse, mutect2
- ABCA12 | c.5272G>A p.V1758I (on ENST00000272895 / NM_173076.3; = p.V1440I on NM_015657.3) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV55955919, COSV99791004; called by muse, mutect2
- ABCA13 | c.2219T>G p.F740C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV70027487; called by muse, mutect2
- ABCA13 | c.8522C>A p.T2841K | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV71286280; called by muse, mutect2
- ADAMTS12 | c.2198A>G p.E733G | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530564365, COSV61260798; called by muse, mutect2, varscan2
- ADAMTS12 | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV61260803; called by muse, mutect2, varscan2
- ADAR | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs770167108, COSV52714300; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100416620; called by muse, mutect2
- ADGRE3 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 15/401 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53730016; called by muse, mutect2
- AGBL1 | c.3296A>C p.K1099T | Missense Mutation (SNP) | VAF 44/356 reads (12%) | PolyPhen benign (0); catalogued as COSV66855424; called by muse, mutect2, varscan2
- AHNAK | c.12488T>G p.V4163G | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs755738333, COSV57210964; called by muse, mutect2, varscan2
- AK9 | c.1160T>G p.M387R | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53420894; called by muse, mutect2, varscan2
- AKAP9 | c.4428A>C p.Q1476H | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV62343794; called by muse, mutect2
- AKAP9 | c.11133A>C p.Q3711H (on ENST00000359028; = p.Q3687H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as rs1283297655, COSV62343806; called by muse, mutect2
- AKNAD1 | c.791T>G p.I264S | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs376331624, COSV62197529; called by muse, varscan2
- AL121899.2 | c.1751A>G p.K584R | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV67350356; called by muse, mutect2
- AL441992.2 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV56913283; called by muse, mutect2
- ALCAM | c.323A>C p.E108A | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV60247284; called by muse, mutect2, varscan2
- ALOX15 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53397284; called by muse, mutect2
- AMPH | c.336A>C p.K112N | Missense Mutation (SNP) | VAF 56/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739713, COSV57758358; called by muse, mutect2
- AMY2B | c.396T>G p.S132R | Missense Mutation (SNP) | VAF 82/730 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV63714978; called by mutect2, varscan2
- ANK2 | c.9739T>C p.S3247P | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1399461128, COSV52156592; called by muse, mutect2, varscan2
- ANK2 | c.11867A>T p.N3956I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV52156603; called by muse, mutect2, varscan2
- ANK3 | c.12053A>G p.E4018G | Missense Mutation (SNP) | VAF 62/451 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as COSV55053517, COSV55053761; called by muse, mutect2, varscan2
- ANKEF1 | c.2141A>G p.K714R | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV65692279; called by muse, mutect2
- ANKRD17 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV58218801; called by muse, mutect2, varscan2
- ANO5 | c.2543T>G p.F848C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61084118; called by muse, mutect2, varscan2
- ARHGAP20 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs773586201, COSV52809620; called by muse, mutect2, varscan2
- ARHGEF6 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV51689607; called by muse, mutect2
- ASCC3 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61227793; called by muse, mutect2, varscan2
- ATP6V0A4 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 53/636 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59474684; called by muse, mutect2
- B3GALT1 | c.184T>G p.S62A | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59908519; called by muse, mutect2, varscan2
- B4GAT1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV60819962; called by muse, mutect2, varscan2
- BACE2 | c.1331T>G p.I444S | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV57739051; called by muse, mutect2, varscan2
- BBS4 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs754792792, COSV51436976, COSV99166501; called by muse, varscan2
- BCO2 | c.650T>G p.F217C | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63062572, COSV63063097; called by muse, mutect2, varscan2
- BIRC6 | c.4679T>C p.L1560P | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70198175, COSV70200265; called by muse, mutect2
- BRDT | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV62864466; called by muse, mutect2
- BRINP1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56297600; called by muse, mutect2
- BTN3A1 | c.963T>C p.S321= | Splice Region (SNP) | VAF 35/305 reads (11%) | catalogued as COSV50024679; called by muse, mutect2, varscan2
- C1QTNF1 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100190049; called by muse, mutect2
- C1orf198 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV64175170; called by muse, mutect2, varscan2
- C2CD2L | c.581A>C p.N194T | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV60883919; called by muse, mutect2, varscan2
- C4orf50 | c.-3843A>G | Splice Region (SNP) | VAF 6/53 reads (11%) | catalogued as COSV51528011; called by muse, mutect2, varscan2
- C5orf34 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 64/462 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60929793; called by muse, mutect2, varscan2
- CACHD1 | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV51551938; called by muse, mutect2
- CCDC43 | c.642A>C p.K214N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV59519683; called by muse, mutect2
- CDON | c.2561A>T p.N854I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54997120; called by muse, mutect2, varscan2
- CEP350 | c.5026T>G p.F1676V | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62601110; called by muse, mutect2, varscan2
- CHCHD2 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.842); catalogued as COSV68169927; called by muse, mutect2, varscan2
- CMTM6 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV52750062; called by muse, mutect2
- CNBD2 | c.500A>C p.E167A | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV62586789; called by muse, mutect2, varscan2
- COL24A1 | c.2213G>C p.G738A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767571746, COSV65305000; called by muse, mutect2, varscan2
- COL6A2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs373782637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2310A>C p.E770D | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV56003189; called by muse, mutect2
- COL6A3 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs778400474, COSV55078994; called by muse, mutect2, varscan2
- CSRNP3 | c.97A>C p.S33R | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58777549; called by muse, mutect2, varscan2
- CYP2A13 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV57837229; called by muse, mutect2
- DCSTAMP | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV52577294; called by muse, mutect2, varscan2
- DEFB129 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV55731321; called by muse, mutect2
- DENND2B | c.2258G>A p.W753* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | catalogued as COSV58202898; called by muse, mutect2, varscan2
- DHDH | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55481944, COSV55482587; called by muse, mutect2
- DIDO1 | c.4180G>A p.E1394K | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV56619685; called by muse, mutect2, varscan2
- DIP2C | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55154395; called by muse, mutect2
- DNAH17 | c.8476A>G p.T2826A | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV101102740; called by mutect2, varscan2
- DNAH5 | c.9767A>C p.K3256T | Missense Mutation (SNP) | VAF 52/826 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54218741; called by muse, mutect2
- DNAH7 | c.6681C>A p.S2227R | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100416741, COSV56760345; called by muse, mutect2, varscan2
- DNAH8 | c.12194A>C p.K4065T | Missense Mutation (SNP) | VAF 10/327 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59439011; called by muse, mutect2
- DNAI3 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54001929; called by muse, mutect2
- DNHD1 | c.12151T>C p.C4051R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV54433946; called by muse, mutect2, varscan2
- DST | c.13218T>G p.D4406E (on ENST00000361203 / NM_001374722.1; = p.D1994E on NM_015548.5) | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as rs1357890163, COSV55009284; called by muse, mutect2, varscan2
- DZIP1L | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.231); catalogued as COSV59520256; called by muse, mutect2, varscan2
- E2F7 | c.1577T>G p.L526R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59739066; called by muse, mutect2, varscan2
- EFCAB2 | c.715-1G>T p.X239_splice (on ENST00000366522; = p.X103_splice on NM_032328.3) | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100833902; called by muse, mutect2, varscan2
- EIF2B5 | c.2006T>C p.I669T (on ENST00000647909; = p.I661T on NM_003907.3) | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56604312; called by muse, mutect2, varscan2
- EMILIN3 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs747443459, COSV60035801; called by muse, mutect2
- EML3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs374119034; called by muse, mutect2, varscan2
- ENC1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV56629367; called by muse, varscan2
- EPB41L2 | c.2078A>T p.K693M | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61354710; called by muse, mutect2, varscan2
- EPHA3 | c.2496T>C p.D832= | Splice Region (SNP) | VAF 33/188 reads (18%) | catalogued as COSV60701769; called by muse, mutect2, varscan2
- EPN3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141972412; called by muse, mutect2, varscan2
- ERBB4 | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as COSV53523425, COSV53526888; called by muse, mutect2, varscan2
- ERCC6 | c.3629A>C p.K1210T | Missense Mutation (SNP) | VAF 90/956 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV63389305; called by muse, mutect2
- ERG | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1028107759, COSV55728910, COSV55732583; called by muse, mutect2, varscan2
- ESYT1 | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV57272452; called by muse, mutect2, varscan2
- FAM91A1 | c.1376T>G p.V459G | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1424915901, COSV58236676; called by muse, mutect2, varscan2
- FARSA | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770712368, COSV53369290; called by muse, mutect2
- FBXO31 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV61148543; called by muse, mutect2, varscan2
- FCGBP | c.10163T>C p.L3388P | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1323265475; called by muse, mutect2, varscan2
- FER1L5 | c.4331A>C p.E1444A (on ENST00000623019; = p.E1417A on NM_001293083.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67606241; called by mutect2, varscan2
- FER1L6 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV67549418; called by mutect2, varscan2
- GABRR1 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65619235, COSV65619439; called by muse, mutect2
- GATB | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | catalogued as COSV56129898; called by muse, mutect2
- GLCCI1 | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 48/932 reads (5%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.991); catalogued as COSV56201227; called by muse, mutect2
- GLI3 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs867192776, COSV67887500; called by muse, mutect2
- GLIPR1L2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1313603216, COSV57553797, COSV57556358; called by muse, mutect2
- GLYAT | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53539056; called by muse, mutect2, varscan2
- GLYATL1 | c.881G>A p.C294Y (on ENST00000317391 / NM_001354699.1; = p.C325Y on NM_080661.4) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55608536; called by muse, mutect2, varscan2
- GOLGA4 | c.5423A>G p.Y1808C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV62710335; called by muse, mutect2
- GRB7 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58447278; called by muse, mutect2, varscan2
- GRIK1 | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58715966; called by muse, mutect2
- GRIK2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as COSV59729281, COSV59761825; called by muse, mutect2, varscan2
- GRIK4 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV70801709; called by muse, mutect2, varscan2
- GRIN2B | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV74204646, COSV74207603; called by muse, mutect2
- GSTO2 | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV58538196; called by muse, mutect2
- GTF2IRD1 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV56085991; called by muse, mutect2
- GTF3C1 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.231); catalogued as COSV62240435; called by muse, mutect2
- HECW1 | c.4129T>G p.L1377V | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs771507037, COSV67827155; called by muse, mutect2
- HECW2 | c.2271A>C p.E757D | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV53656503; called by muse, mutect2, varscan2
- HSP90AB1 | c.1756T>C p.S586P | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV62334126; called by muse, mutect2
- IFNA5 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 26/621 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52386749; called by muse, mutect2
- IFT140 | c.3029T>G p.L1010R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54152381; called by muse, mutect2
- IFT57 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52709173; called by muse, mutect2, varscan2
- IGSF10 | c.7166T>C p.L2389P | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV56375875; called by muse, mutect2, varscan2
- IL1RAPL1 | c.187A>C p.N63H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56253904; called by muse, mutect2, varscan2
- INPPL1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs781357595, COSV53354279; called by muse, mutect2, varscan2
- IRX1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57359002; called by muse, mutect2
- ITGA9 | c.1465G>T p.V489L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV53240542; called by muse, mutect2, varscan2
- ITIH6 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54488369; called by muse, mutect2
- ITPR2 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54383886; called by muse, mutect2, varscan2
- ITSN2 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61945887; called by muse, mutect2
- JSRP1 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV55554407; called by muse, mutect2, varscan2
- KANSL1L | c.247A>C p.M83L | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV55991484; called by muse, mutect2
- KCNAB1 | c.357+2T>C p.X119_splice (on ENST00000490337 / NM_172160.3; = p.X108_splice on NM_003471.3) | Splice Site (SNP) | VAF 20/350 reads (6%) | catalogued as COSV56744331; called by muse, mutect2
- KCNH8 | c.1796T>G p.L599R | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60461506, COSV60466752; called by muse, mutect2, varscan2
- KCNJ16 | c.819A>C p.K273N | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as COSV52252476; called by muse, mutect2, varscan2
- KCTD14 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV62001324; called by muse, mutect2, varscan2
- KDM6A | c.1961C>G p.P654R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV65039188; called by muse, mutect2, varscan2
- KIF17 | c.2695G>A p.V899I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs774513929, COSV56117605; called by muse, mutect2, varscan2
- KLHL15 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as COSV60140003; called by muse, mutect2, varscan2
- KLHL23 | c.1161G>C p.E387D | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55866744, COSV55869138; called by muse, mutect2, varscan2
- KLHL4 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV64141361; called by muse, mutect2, varscan2
- KRT34 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67449656; called by muse, mutect2, varscan2
- KRTAP5-8 | c.135T>G p.C45W | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV68324550; called by muse, mutect2, varscan2
- KRTAP5-9 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV73200183; called by muse, mutect2, varscan2
- KY | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101414974; called by muse, mutect2
- LACRT | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 61/427 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.181); catalogued as COSV57688194; called by muse, mutect2, varscan2
- LAMB4 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200729086, COSV52717488; called by muse, mutect2, varscan2
- LMCD1 | c.41A>T p.K14M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV50087885; called by muse, mutect2
- LRIG2 | c.1911A>T p.K637N | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63161670; called by muse, mutect2
- LRP1B | c.13056A>T p.E4352D | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV67207696; called by muse, mutect2, varscan2
- LRRC7 | c.4487G>A p.G1496E (on ENST00000651989 / NM_001370785.2; = p.G1416E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50441981, COSV99230752; called by muse, mutect2
- LRRC8C | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64997053; called by muse, mutect2, varscan2
- LUC7L2 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV54925428; called by muse, mutect2
- MAP3K13 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 21/219 reads (10%) | catalogued as COSV53987480; called by muse, mutect2, varscan2
- MAPRE2 | c.743A>C p.N248T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV55818600; called by muse, mutect2
- MASTL | c.2397A>C p.E799D (on ENST00000375940 / NM_001372029.1; = p.E798D on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV60910449; called by muse, mutect2, varscan2
- MCM7 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57995734; called by muse, mutect2, varscan2
- MED13L | c.1444A>G p.R482G | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV56118722; called by muse, mutect2, varscan2
- MGA | c.2846A>C p.N949T | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV54952292; called by muse, mutect2
- MIIP | c.966T>G p.I322M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV52427476; called by muse, mutect2
- MRC2 | c.203G>C p.C68S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57638896; called by muse, mutect2
- MSL3 | c.337T>A p.L113I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56492641; called by muse, mutect2
- MUC16 | c.18109G>A p.G6037R | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs771448044, COSV67460293; called by muse, mutect2, varscan2
- MUC16 | c.5122A>C p.T1708P | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV67460308; called by muse, mutect2
- MYEF2 | c.1737C>A p.C579* | Nonsense Mutation (SNP) | VAF 19/170 reads (11%) | catalogued as COSV51047148; called by muse, mutect2, varscan2
- MYH13 | c.4499A>G p.E1500G | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV52825740; called by muse, mutect2, varscan2
- MYH15 | c.4862T>A p.I1621N | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56308246; called by muse, mutect2
- MYO1A | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as COSV55653292; called by muse, mutect2, varscan2
- MYOM2 | c.3324T>A p.D1108E | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV50708645; called by muse, mutect2, varscan2
- MYOZ2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV61084636; called by muse, mutect2, varscan2
- NDUFA8 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV65653356; called by muse, mutect2
- NEB | c.791T>G p.F264C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV51115910; called by muse, mutect2
- NETO2 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as COSV57452437; called by muse, mutect2
- NLRC4 | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61592242; called by muse, mutect2
- NMT2 | c.667A>C p.K223Q | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV65381988; called by muse, mutect2, varscan2
- NOX4 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs55696571, COSV54451449; called by muse, mutect2
- NR1H2 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.515); catalogued as COSV53800573; called by muse, mutect2, varscan2
- NR3C1 | c.2192A>C p.N731T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV51542123; called by muse, mutect2
- NRXN3 | c.2591G>A p.G864E (on ENST00000335750 / NM_001330195.2; = p.G491E on NM_004796.6) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745506360, COSV59738874; called by muse, mutect2, varscan2
- NUP37 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51837574, COSV99195846; called by muse, mutect2, varscan2
- NUP54 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs781147108, COSV53575175; called by muse, mutect2, varscan2
- NUP88 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV56704865; called by muse, mutect2, varscan2
- NXPE4 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64943667; called by muse, mutect2, varscan2
- OLFML2B | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs759374069, COSV54193801; called by muse, mutect2, varscan2
- OR5H1 | c.888A>T p.Q296H | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63402220; called by muse, mutect2, varscan2
- OR5T3 | c.95A>C p.D32A | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57380180; called by muse, mutect2
- PAMR1 | c.1963A>C p.T655P (on ENST00000619888 / NM_001001991.3; = p.T672P on NM_015430.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV53511342; called by muse, mutect2
- PARP1 | c.2422T>A p.S808T | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV64690064; called by muse, mutect2
- PARP9 | c.1481A>C p.N494T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV64450476; called by muse, mutect2, varscan2
- PBRM1 | c.3161A>T p.E1054V (on ENST00000296302 / NM_001366071.2; = p.E1029V on NM_018313.5) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV56271540; called by muse, mutect2, varscan2
- PC | c.2780G>A p.S927N | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1339631161, COSV58992493; called by muse, mutect2
- PCDHGC4 | c.418T>G p.L140V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV52749327; called by muse, mutect2, varscan2
- PDGFD | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56375106; called by muse, mutect2, varscan2
- PDZD2 | c.3550A>C p.K1184Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV56856314; called by muse, mutect2
- PDZRN4 | c.1961G>T p.C654F (on ENST00000402685 / NM_001164595.2; = p.C396F on NM_013377.4) | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100114892; called by muse, mutect2
- PIK3R3 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773472193, COSV53104373; called by muse, mutect2, varscan2
- PLEKHH2 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1339805503, COSV56752301; called by muse, mutect2, varscan2
- PLXNA4 | c.5662A>C p.T1888P | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV58118623; called by muse, mutect2, varscan2
- PNMA8A | c.841A>C p.S281R | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58136674; called by muse, mutect2
- POGZ | c.3223T>G p.F1075V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51851229; called by muse, mutect2
- POLN | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67024735; called by muse, mutect2, varscan2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2
- PPA2 | c.708T>G p.N236K (on ENST00000341695 / NM_176869.3; = p.N207K on NM_006903.4) | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV58994717; called by muse, mutect2, varscan2
- PPIP5K2 | c.1686A>G p.I562M | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58604897; called by muse, mutect2, varscan2
- PPP1R7 | c.794A>C p.E265A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV52144362; called by muse, mutect2, varscan2
- PRAG1 | c.4202A>C p.K1401T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100422411; called by muse, varscan2
- PRAMEF4 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV52438208; called by muse, mutect2, varscan2
- PRDM9 | c.1586G>A p.C529Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV57005294; called by muse, mutect2
- PRIMPOL | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV59248445; called by muse, mutect2, varscan2
- PRMT3 | c.1002T>A p.F334L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV58176315; called by muse, mutect2, varscan2
- PROCA1 | c.361A>C p.T121P (on ENST00000439862 / NM_001366301.1; = p.T93P on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56386225; called by muse, mutect2, varscan2
- PSMD2 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV59529457; called by muse, mutect2, varscan2
- PTGES2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs779011818, COSV52968368; called by muse, mutect2, varscan2
- PTPN13 | c.3971A>T p.D1324V (on ENST00000411767 / NM_080683.3; = p.D1305V on NM_006264.3) | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57405976; called by muse, mutect2, varscan2
- PTPRD | c.732T>A p.N244K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV61939072; called by muse, mutect2, varscan2
- PTPRS | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.173); catalogued as COSV53617082; called by muse, mutect2, varscan2
- RADX | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 8/243 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.147); catalogued as COSV65318337; called by muse, mutect2
- RALY | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55780857; called by muse, mutect2, varscan2
- RANBP2 | c.2227A>C p.K743Q | Missense Mutation (SNP) | VAF 57/555 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV51699676; called by muse, mutect2, varscan2
- RECK | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as rs1198354875, COSV65035144; called by muse, mutect2
- REL | c.555A>C p.E185D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV54363664; called by muse, mutect2, varscan2
- RND2 | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56816388; called by muse, mutect2
- RNF213 | c.10153A>T p.I3385F | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV60395222; called by muse, mutect2, varscan2
- RTF1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67477964; called by muse, mutect2, varscan2
- RYR2 | c.7268T>C p.L2423S | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63679686; called by muse, mutect2, varscan2
- SBNO1 | c.2591A>C p.K864T (on ENST00000420886; = p.K863T on NM_018183.5) | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV57340768; called by muse, mutect2, varscan2
- SCN11A | c.1240A>T p.I414L | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56568852; called by muse, mutect2
- SEC31A | c.2032A>T p.N678Y (on ENST00000355196 / NM_001318120.1; = p.N639Y on NM_016211.4) | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV52344300; called by muse, mutect2, varscan2
- SELE | c.1814A>G p.K605R | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV60974993; called by muse, mutect2, varscan2
- SERPINE2 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as rs373891026; called by muse, mutect2
- SETDB1 | c.3486A>T p.K1162N | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54980857; called by muse, mutect2
- SF1 | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV57112954; called by muse, mutect2, varscan2
- SGO2 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV63414866, COSV63417137; called by muse, mutect2, varscan2
- SGO2 | c.2514A>C p.K838N | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV63414874; called by muse, mutect2, varscan2
- SHOX2 | c.601C>G p.Q201E (on ENST00000441443 / NM_006884.3; = p.Q225E on NM_003030.4) | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV67463790, COSV67463901; called by muse, mutect2, varscan2
- SIPA1L2 | c.4301A>T p.Q1434L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV53388652; called by muse, mutect2, varscan2
- SLC10A4 | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV56718530; called by muse, mutect2
- SLC16A10 | c.1431A>C p.Q477H | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); catalogued as COSV64354138; called by muse, mutect2
- SLC16A14 | c.1394A>C p.D465A | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54617938; called by muse, mutect2
- SLC17A1 | c.1363A>C p.I455L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV55078384; called by muse, mutect2
- SLC38A11 | c.295T>G p.F99V (on ENST00000409149 / NM_001351539.1; = p.F77V on NM_173512.2) | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV58053237; called by muse, mutect2, varscan2
- SLC44A1 | c.1533C>A p.F511L | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58263902; called by muse, varscan2
- SLC49A4 | c.1311T>G p.F437L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV53746536; called by muse, mutect2, varscan2
- SLC5A8 | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV73310540; called by muse, mutect2, varscan2
- SLC6A11 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54392543; called by muse, mutect2, varscan2
- SLC9A2 | c.943T>G p.F315V | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52131077; called by muse, mutect2
- SLC9C2 | c.46T>G p.L16V | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV62945257; called by muse, mutect2, varscan2
- SNX30 | c.351T>C p.S117= | Splice Region (SNP) | VAF 6/132 reads (5%) | catalogued as COSV65292712; called by muse, mutect2
- SPECC1 | c.1146A>C p.E382D | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54956567; called by muse, mutect2, varscan2
- SPTAN1 | c.2267A>C p.K756T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV100823732; called by muse, mutect2
- SPTB | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67631124; called by muse, mutect2, varscan2
- SPTBN1 | c.4397A>C p.K1466T | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV61687726; called by muse, mutect2
- SREK1 | c.373T>G p.F125V | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV52332602; called by muse, mutect2
- SRGAP3 | c.1975T>G p.F659V | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64532400; called by muse, mutect2, varscan2
- STAG1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV52607191; called by muse, mutect2
- STON2 | c.11T>C p.L4S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV50843607; called by muse, mutect2
- STYXL2 | c.1670A>T p.H557L | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs771053710, COSV54804123; called by muse, mutect2
- SYNDIG1 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV65232448; called by muse, mutect2, varscan2
- TACR3 | c.1121G>A p.C374Y | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59200457; called by muse, mutect2, varscan2
- TAF1B | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55155439; called by muse, mutect2, varscan2
- TAF4 | c.1522-1G>A p.X508_splice | Splice Site (SNP) | VAF 42/175 reads (24%) | catalogued as COSV53336826; called by muse, mutect2, varscan2
- TAS1R1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as rs139619592; called by muse, mutect2, varscan2
- TBCEL | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV52459412; called by muse, mutect2
- TBCK | c.2480A>T p.E827V (on ENST00000273980 / NM_001163436.4; = p.E764V on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV56754483; called by muse, mutect2, varscan2
- TCF7L2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60504932; called by muse, mutect2, varscan2
- TCFL5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs780872850, COSV53896319; called by muse, mutect2
- TCTE1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65255410, COSV65256410; called by muse, mutect2, varscan2
- TDO2 | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV70809036; called by muse, mutect2
- TEX10 | c.30T>G p.D10E | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66515046; called by muse, mutect2
- TGM1 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.339); catalogued as COSV52862787; called by muse, mutect2, varscan2
- THOC2 | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV55544392; called by muse, mutect2, varscan2
- TMC7 | c.812G>T p.S271I | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100432350, COSV58582902; called by muse, mutect2, varscan2
- TNN | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs763519873, COSV53422647; called by muse, mutect2, varscan2
- TPO | c.2480A>T p.D827V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61099847; called by muse, mutect2, varscan2
- TRAF7 | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV58213924; called by muse, mutect2, varscan2
- TRIOBP | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 35/341 reads (10%) | catalogued as rs776862322, COSV60376313; called by muse, varscan2
- TRO | c.2139A>C p.E713D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV51498237, COSV51500431; called by muse, mutect2, varscan2
- TRPM3 | c.4251T>G p.D1417E (on ENST00000357533 / NM_001366142.2; = p.D1272E on NM_020952.6) | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV62584475; called by muse, mutect2
- TSSK6 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53063260; called by muse, mutect2, varscan2
- TTC27 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58650774; called by muse, mutect2
- TTN | c.39581T>G p.L13194R (on ENST00000591111; = p.L5770R on NM_003319.4) | Missense Mutation (SNP) | VAF 54/580 reads (9%) | PolyPhen probably damaging (0.988); catalogued as COSV59995707; called by muse, mutect2
- TTN | c.18755C>A p.T6252N (on ENST00000591111; = p.T5325N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | PolyPhen benign (0.011); catalogued as COSV59995739; called by muse, mutect2, varscan2
- TTN | c.14870C>T p.A4957V (on ENST00000591111; = p.A4030V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/406 reads (10%) | PolyPhen benign (0.322); catalogued as COSV59995752; called by muse, mutect2
- UBQLNL | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 13/341 reads (4%) | catalogued as COSV66493124; called by muse, mutect2
- UGT2B7 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV59442948; called by muse, mutect2, varscan2
- UGT2B7 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV59441838, COSV59445585; called by muse, mutect2, varscan2
- UGT3A1 | c.610T>A p.F204I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV57097374; called by muse, mutect2
- UGT3A2 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.404); catalogued as COSV56929978; called by muse, mutect2, varscan2
- UNC13C | c.5054A>C p.Y1685S | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52863910; called by muse, mutect2
- UNC79 | c.3198A>C p.K1066N (on ENST00000393151 / NM_001346218.2; = p.K889N on NM_020818.5) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56383431; called by muse, mutect2
- UPF2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); catalogued as rs1160241745, COSV62660056; called by muse, mutect2
- URGCP | c.748T>C p.F250L (on ENST00000453200 / NM_001077663.3; = p.F241L on NM_017920.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56246783, COSV56251145; called by muse, mutect2, varscan2
- USP13 | c.629A>T p.K210M | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55864800; called by muse, mutect2
- UTRN | c.8176G>A p.D2726N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62308935; called by muse, mutect2, varscan2
- VASH2 | c.956A>T p.Q319L (on ENST00000517399 / NM_001301056.2; = p.Q275L on NM_024749.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV55117510; called by muse, mutect2, varscan2
- VPS13D | c.4430A>C p.E1477A | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV50633240; called by muse, mutect2, varscan2
- VPS8 | c.3450G>A p.M1150I (on ENST00000625842 / NM_001349294.1; = p.M1148I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV54983745; called by muse, varscan2
- WIF1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201325270, COSV54131027; called by muse, mutect2, varscan2
- WRAP73 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54560870; called by muse, mutect2, varscan2
- WWC1 | c.942G>A p.R314= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54649621; called by muse, mutect2, varscan2
- XIRP2 | c.1504G>A p.A502T (on ENST00000628543; = p.A677T on NM_152381.6) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV54694422, COSV99747461; called by muse, mutect2, varscan2
- XKR6 | c.1926A>C p.*642Yext*24 | Nonstop Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as COSV100440661, COSV58655532; called by muse, mutect2, varscan2
- XRCC5 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV67535932; called by muse, mutect2, varscan2
- XRCC6 | c.1493T>G p.M498R | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.182); catalogued as COSV63752689; called by muse, mutect2, varscan2
- ZBTB11 | c.2630T>G p.M877R | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57244818; called by muse, mutect2, varscan2
- ZBTB24 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57781794; called by muse, mutect2, varscan2
- ZCCHC7 | c.1282A>G p.R428G | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV60956648; called by muse, mutect2
- ZDHHC23 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 59/468 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV57629303; called by muse, mutect2, varscan2
- ZNF112 | c.521A>C p.Y174S (on ENST00000337401 / NM_001083335.2; = p.Y168S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100495514, COSV61619669; called by muse, mutect2
- ZNF160 | c.2369A>C p.K790T | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61999452; called by muse, mutect2, varscan2
- ZNF180 | c.897A>C p.K299N | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.287); catalogued as COSV55420769, COSV99659631; called by muse, mutect2
- ZNF20 | c.141A>G p.G47= | Splice Region (SNP) | VAF 13/126 reads (10%) | catalogued as COSV61998996; called by muse, mutect2
- ZNF208 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.111); catalogued as rs1327591772, COSV68103915; called by muse, mutect2, varscan2
- ZNF211 | c.875A>G p.K292R (on ENST00000347302 / NM_198855.4; = p.K305R on NM_006385.5) | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV53741403; called by muse, mutect2, varscan2
- ZNF223 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV71571853; called by muse, mutect2, varscan2
- ZNF225 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.887); catalogued as COSV53471428; called by muse, mutect2
- ZNF257 | c.340A>G p.R114G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV71306196, COSV71306850; called by muse, mutect2, varscan2
- ZNF407 | c.1628T>C p.L543S | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs771803706, COSV55249830; called by muse, mutect2, varscan2
- ZNF425 | c.1915T>A p.S639T | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV65201088; called by muse, mutect2
- ZNF43 | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61683616, COSV61685304; called by muse, mutect2
- ZNF560 | c.2026A>C p.K676Q | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV56867281; called by muse, mutect2
- ZNF564 | c.1527A>C p.Q509H | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.445); catalogued as COSV59434810; called by muse, mutect2, varscan2
- ZNF585A | c.2264T>G p.F755C (on ENST00000292841 / NM_001288800.2; = p.F700C on NM_152655.3) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53062989; called by muse, mutect2
- ZNF677 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV61720059; called by muse, mutect2, varscan2
- ZNF780A | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV61815169; called by muse, mutect2
- ZNF808 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63119452; called by muse, mutect2, varscan2
- CAV3 | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2
- EVPL | c.4193_4195del p.E1398del | In Frame Del (DEL) | VAF 15/99 reads (15%) | called by pindel, varscan2
- FGD1 | c.2796_2797insC p.E933Rfs*18 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- KIR2DS4 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 64/852 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- MARK4 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.421); called by muse, mutect2
- PRAMEF10 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV34 | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); called by muse, mutect2
- TTN | c.32332dup p.I10778Nfs*9 (on ENST00000591111; = p.I9851Nfs*9 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/106 reads (9%) | called by mutect2, pindel
- ZNF658 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDA | c.1691T>A p.M564K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- AC004922.1 | c.1230G>A p.V410= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV53163137; called by muse, mutect2
- ADGRB1 | c.3900C>T p.P1300= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs371373603; called by muse, mutect2, varscan2
- ADRB1 | c.339G>A p.P113= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV65167790; called by muse, mutect2, varscan2
- AHNAK | c.3297A>T p.P1099= | Silent (SNP) | VAF 39/369 reads (11%) | catalogued as COSV57210979, COSV99947915; called by muse, mutect2, varscan2
- ALDH1A1 | c.9C>A p.S3= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs770312696, COSV52790664; called by muse, mutect2, varscan2
- APOB | c.4998G>A p.V1666= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs1234999331, COSV51932125; called by muse, mutect2
- BRSK1 | c.817A>C p.R273= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV58665900; called by muse, mutect2
- CAMSAP2 | c.1260T>G p.V420= (on ENST00000236925 / NM_001297707.2; = p.V409= on NM_203459.3) | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as COSV52669456; called by muse, mutect2, varscan2
- CDHR1 | c.75G>A p.P25= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1319670529, COSV60561553; called by muse, mutect2, varscan2
- CENPF | c.4152G>A p.L1384= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV65274245; called by muse, mutect2, varscan2
- CFAP61 | c.561A>G p.K187= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as COSV55626402; called by muse, varscan2
- CLEC10A | c.930G>A p.Q310= (on ENST00000254868 / NM_182906.4; = p.Q286= on NM_006344.4) | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV54700866; called by muse, mutect2
- CLSTN2 | c.1701C>T p.I567= | Silent (SNP) | VAF 45/418 reads (11%) | catalogued as COSV71720308; called by muse, mutect2
- CMIP | c.417C>T p.V139= (on ENST00000537098 / NM_198390.2; = p.V45= on NM_030629.3) | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs764628932, COSV73344854; called by muse, mutect2, varscan2
- CMTR1 | c.1425C>T p.S475= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs752607598, COSV65090126; called by muse, mutect2, varscan2
- CPEB1 | c.1278C>T p.F426= (on ENST00000617958; = p.F361= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs754255400, COSV55617468; called by muse, mutect2, varscan2
- CPLANE1 | c.9276A>G p.K3092= | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as COSV57057780; called by muse, mutect2
- CPS1 | c.4239A>G p.Q1413= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV51807883; called by muse, mutect2, varscan2
- CSMD2 | c.10065T>G p.A3355= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV53902938; called by muse, mutect2
- DAW1 | c.690A>C p.S230= | Silent (SNP) | VAF 31/345 reads (9%) | catalogued as COSV59364836; called by muse, mutect2
- DCBLD1 | c.483A>C p.R161= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV51640092; called by muse, mutect2
- DHX16 | c.1365A>G p.R455= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV64563674; called by muse, mutect2
- DPY19L2 | c.261T>C p.N87= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV60542892; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1014T>C p.L338= (on ENST00000361735 / NM_015935.5; = p.L252= on NM_014955.3) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV62282881; called by muse, mutect2, varscan2
- GRAMD1C | c.1329T>G p.S443= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as COSV63982546; called by muse, mutect2, varscan2
- HCK | c.969G>A p.V323= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV52941918; called by muse, mutect2, varscan2
- HOXB1 | c.682C>T p.L228= | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV53316978; called by muse, mutect2
- IGHA2 | c.858C>T p.R286= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- IL17RD | c.1761T>G p.V587= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV56337063; called by muse, mutect2, varscan2
- ITGA8 | c.2124T>C p.F708= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV65227492; called by muse, mutect2, varscan2
- ITPR3 | c.1299A>G p.S433= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs753117025, COSV65408124; called by muse, mutect2, varscan2
- JRKL | c.1419G>A p.E473= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs753799377, COSV53593076, COSV53594824; called by muse, mutect2, varscan2
- KCNJ8 | c.1020C>A p.S340= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as COSV53715954; called by muse, mutect2, varscan2
- KCNK13 | c.477G>A p.S159= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs747392807, COSV56412400; called by muse, mutect2, varscan2
- KDM4B | c.2214G>A p.E738= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV50216225; called by muse, mutect2, varscan2
- KIAA1210 | c.3711A>G p.Q1237= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs749135803, COSV101274241, COSV68176724; called by muse, mutect2, varscan2
- L3MBTL3 | c.1464C>T p.N488= | Silent (SNP) | VAF 26/433 reads (6%) | catalogued as rs750029297, COSV62385574; called by muse, mutect2
- LRP1B | c.10986T>C p.S3662= | Silent (SNP) | VAF 54/609 reads (9%) | catalogued as COSV67207699; called by muse, mutect2
- MACF1 | c.5880C>T p.A1960= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV57117671; called by muse, mutect2, varscan2
- MATN2 | c.1701A>G p.K567= | Silent (SNP) | VAF 66/592 reads (11%) | catalogued as COSV54709858; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2, varscan2
- MED9 | c.285G>A p.Q95= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV51957374; called by muse, mutect2
- MICAL2 | c.5350A>C p.R1784= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV56285492; called by muse, mutect2, varscan2
- MSANTD3 | c.201C>T p.F67= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV58492520; called by muse, mutect2, varscan2
- MUC16 | c.33123G>A p.V11041= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV67460287; called by muse, mutect2
- MYO3B | c.564A>G p.R188= | Silent (SNP) | VAF 61/541 reads (11%) | catalogued as COSV58701040; called by muse, mutect2, varscan2
- NBEA | c.2163T>C p.D721= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV59777327; called by muse, mutect2, varscan2
- NBEA | c.8619C>T p.D2873= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs368738439; called by muse, mutect2, varscan2
- NFIB | c.186C>T p.L62= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as rs770325375, COSV66620547; called by muse, mutect2, varscan2
- NKX2-2 | c.36C>T p.V12= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV65819422; called by muse, mutect2, varscan2
- NME6 | c.336A>G p.P112= (on ENST00000415053; = p.P120= on NM_005793.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV56640522; called by muse, mutect2, varscan2
- NOVA1 | c.381G>T p.V127= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as COSV57475419, COSV57485996; called by muse, mutect2
- OLFM1 | c.792C>T p.Y264= (on ENST00000371793 / NM_001282611.2; = p.Y246= on NM_014279.5) | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV53277832; called by muse, mutect2, varscan2
- OR10G2 | c.571A>C p.R191= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- OR10Z1 | c.654C>T p.Y218= | Silent (SNP) | VAF 31/339 reads (9%) | catalogued as rs574727322, COSV63524141; called by muse, mutect2
- OR1A1 | c.891T>C p.A297= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV58403587; called by muse, mutect2, varscan2
- OR4M1 | c.420C>T p.L140= | Silent (SNP) | VAF 46/990 reads (5%) | catalogued as COSV60060599; called by muse, mutect2
- OSCP1 | c.666A>G p.K222= (on ENST00000356637 / NM_001330493.1; = p.K212= on NM_145047.5) | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV52485674; called by muse, mutect2
- PAX4 | c.687G>A p.E229= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV58388290; called by muse, mutect2, varscan2
- PBXIP1 | c.888T>G p.L296= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as COSV63777004; called by muse, mutect2, varscan2
- PCBD1 | c.154A>C p.R52= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV54738330; called by muse, mutect2
- PCDH17 | c.2925A>C p.V975= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV64973439; called by muse, mutect2
- PCDH9 | c.3294T>C p.S1098= (on ENST00000377865 / NM_203487.3; = p.S1064= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as COSV60543425; called by muse, mutect2, varscan2
- PLEKHG3 | c.3339A>G p.S1113= (on ENST00000394691; = p.S1169= on NM_001308147.2) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55979240; called by muse, mutect2, varscan2
- PPP2R5B | c.217C>T p.L73= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV51210117; called by muse, mutect2, varscan2
- PRPF31 | c.775C>T p.L259= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV58085056; called by muse, mutect2
- PSMB11 | c.555C>T p.Y185= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs375515840; called by muse, mutect2, varscan2
- PSPC1 | c.1341A>T p.G447= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as COSV100142432; called by muse, mutect2
- R3HCC1L | c.765A>C p.G255= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV54400594; called by muse, mutect2
- RLIM | c.363T>C p.S121= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV60326130; called by muse, mutect2
- SAMD9L | c.1128T>C p.S376= | Silent (SNP) | VAF 20/677 reads (3%) | catalogued as COSV59080885; called by muse, mutect2
- SCARB1 | c.735C>T p.F245= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55546594; called by muse, mutect2, varscan2
- SLITRK5 | c.2829G>A p.P943= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as rs771423229, COSV61522231, COSV61523393; called by muse, mutect2, varscan2
- SMYD4 | c.1029A>T p.T343= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV59711372; called by muse, mutect2, varscan2
- SPATA31D1 | c.2295C>T p.S765= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV100782864; called by muse, mutect2
- SPEF2 | c.873A>G p.K291= | Silent (SNP) | VAF 15/194 reads (8%) | catalogued as COSV56796090; called by muse, mutect2
- TCTN3 | c.1467T>G p.T489= | Silent (SNP) | VAF 57/245 reads (23%) | catalogued as COSV56446863; called by muse, mutect2, varscan2
- THSD7B | c.2430A>G p.L810= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV55676358; called by muse, mutect2
- TRAF3IP3 | c.1155A>G p.R385= | Silent (SNP) | VAF 4/92 reads (4%) | catalogued as COSV50552114; called by muse, mutect2
- USP10 | c.1806C>T p.I602= | Silent (SNP) | VAF 44/242 reads (18%) | catalogued as COSV54748387; called by muse, mutect2, varscan2
- USP26 | c.222T>G p.T74= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV63708478; called by muse, mutect2, varscan2
- USP37 | c.2031A>G p.E677= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as COSV51442810; called by muse, varscan2
- YIPF4 | c.567A>G p.G189= | Silent (SNP) | VAF 26/314 reads (8%) | catalogued as COSV53213435; called by muse, mutect2
- YTHDF2 | c.1116A>C p.G372= | Silent (SNP) | VAF 29/207 reads (14%) | catalogued as rs1266095665, COSV65723103; called by muse, mutect2, varscan2
- ZC4H2 | c.351G>A p.L117= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV62003038; called by muse, mutect2, varscan2
- ZNF180 | c.360A>G p.K120= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV55420784; called by muse, mutect2, varscan2
- ZNF823 | c.1392T>C p.T464= (on ENST00000341191 / NM_001297610.2; = p.T420= on NM_017507.2) | Silent (SNP) | VAF 30/223 reads (13%) | catalogued as COSV57873382; called by muse, varscan2
- ZNF846 | c.951A>G p.K317= | Silent (SNP) | VAF 28/260 reads (11%) | catalogued as COSV67412008; called by muse, mutect2, varscan2
- CDH6 | c.*2C>T | 3'UTR (SNP) | VAF 19/273 reads (7%) | catalogued as COSV99419722; called by muse, mutect2
- DNM2 | c.1336-1044T>C | Intron (SNP) | VAF 18/158 reads (11%) | catalogued as COSV58960197; called by muse, mutect2, varscan2
- HDAC9 | c.2577+41T>G | Intron (SNP) | VAF 19/177 reads (11%) | catalogued as rs1054526567; called by muse, mutect2, varscan2
- HOATZ | chr11:111513448 A>G | 5'Flank (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- MGA | c.4435-141G>A | Intron (SNP) | VAF 29/262 reads (11%) | catalogued as rs1261474616, COSV54952300; called by muse, varscan2
- MIR369 | n.13C>T | RNA (SNP) | VAF 23/192 reads (12%) | catalogued as rs1315076023; called by muse, mutect2, varscan2
- NAA20 | c.53+589C>T | Intron (SNP) | VAF 39/343 reads (11%) | catalogued as COSV100131728; called by muse, mutect2, varscan2
- TNNI1 | c.-1C>T | 5'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100270130, COSV100270352; called by muse, mutect2, varscan2
- ZNF655 | c.136+3343A>C | Intron (SNP) | VAF 20/166 reads (12%) | catalogued as COSV99402211; called by muse, mutect2, varscan2
